Somatic mutation profile of tumor specimen TCGA-HF-A5NB-01A (aliquot TCGA-HF-A5NB-01A-11D-A31L-08) from TCGA case TCGA-HF-A5NB, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G3.
Specimen TCGA-HF-A5NB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cdbe169-27dc-4051-90f4-7ba52af9909e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HF-A5NB-10A (Blood Derived Normal), aliquot TCGA-HF-A5NB-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/39b8b948-c44e-4d90-8cb9-1ecd013bac00

The open-access MAF lists 1,653 somatic variants for this specimen: 1,267 protein-altering or splice-affecting, 349 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 820, Silent 349, Frame Shift Del 307, Frame Shift Ins 63, Nonsense Mutation 29, Splice Site 24, In Frame Del 15, Intron 14, RNA 7, Splice Region 7, 3'UTR 5, 5'Flank 5.

Variants (750 of 1,653; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5012del p.N1671Ifs*4 (on ENST00000272895 / NM_173076.3; = p.N1353Ifs*4 on NM_015657.3) | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | catalogued as rs387906285, CD051281; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGL | c.4221del p.K1407Nfs*8 | Frame Shift Del (DEL) | VAF 62/148 reads (42%) | catalogued as rs786204655; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 24/51 reads (47%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATM | c.1495C>T p.Q499* | Nonsense Mutation (SNP) | VAF 32/134 reads (24%) | catalogued as rs1555071075, COSV53752784, COSV99586825; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMPR2 | c.246A>C p.Q82H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1085307185, CM024281, COSV101001160, COSV65813180; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.5551C>T p.R1851C | Missense Mutation (SNP) | VAF 80/181 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs763253161, COSV99268258, COSV99271875; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DLD | c.633dup p.V212Sfs*32 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs1040811473; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DYRK1A | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as rs724159949, CM1413207, COSV58294256; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IRF6 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 59/90 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121434227, CM022386, CM090290, CM105239, COSV100883994, COSV65419472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 9/16 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- LRPPRC | c.3147del p.A1051Hfs*6 | Frame Shift Del (DEL) | VAF 12/32 reads (38%) | catalogued as rs769022521; ClinVar: pathogenic; called by mutect2, varscan2
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 20/57 reads (35%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 37/93 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PROK2 | c.297del p.F99Lfs*28 (on ENST00000295619 / NM_001126128.2; = p.F78Lfs*28 on NM_021935.4) | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- A2M | c.1877A>G p.D626G | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV100588380; called by muse, varscan2
- AARD | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs1437748834, COSV100991801; called by muse, mutect2, varscan2
- AASDH | c.1210+2T>C p.X404_splice | Splice Site (SNP) | VAF 30/100 reads (30%) | catalogued as COSV99220548; called by muse, mutect2, varscan2
- ABCA12 | c.4642G>A p.A1548T (on ENST00000272895 / NM_173076.3; = p.A1230T on NM_015657.3) | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754893598, COSV55974837; called by muse, mutect2, varscan2
- ABCA13 | c.7735del p.I2579* | Frame Shift Del (DEL) | VAF 43/108 reads (40%) | catalogued as COSV71288654; called by mutect2, varscan2
- ABCA2 | c.4282C>T p.R1428C (on ENST00000614293; = p.R1398C on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs368482288, COSV99686677; called by muse, mutect2, varscan2
- ABCA4 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100933001; called by muse, mutect2, varscan2
- ABCA5 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs150760061; called by muse, mutect2, varscan2
- ABCA9 | c.4621del p.Q1541Rfs*11 | Frame Shift Del (DEL) | VAF 49/134 reads (37%) | catalogued as COSV100382730; called by mutect2, varscan2
- ABCC12 | c.2425G>A p.A809T | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs776302423, COSV60916050; called by muse, mutect2, varscan2
- ABCC12 | c.353T>C p.F118S | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100252043; called by muse, mutect2, varscan2
- ABCC3 | c.4073G>A p.G1358D | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99558555; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABCF3 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs374622062; called by muse, mutect2, varscan2
- ABHD3 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs142326991; called by muse, mutect2, varscan2
- AC090517.4 | c.1377del p.G460Efs*13 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs148356323; called by mutect2, pindel, varscan2
- AC097637.1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs970028838, COSV100564418; called by muse, mutect2, varscan2
- AC100868.1 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.041); catalogued as rs775171724, COSV51852839; called by muse, mutect2, varscan2
- ACACB | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 73/152 reads (48%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs551468976, COSV58134994; called by muse, mutect2, varscan2
- ACADM | c.16G>T p.G6W | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV100897583; called by muse, mutect2, varscan2
- ACAN | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100716786; called by muse, mutect2, varscan2
- ACAP2 | c.1583del p.K528Sfs*12 | Frame Shift Del (DEL) | VAF 19/49 reads (39%) | catalogued as rs1560211584; called by mutect2, pindel, varscan2
- ACIN1 | c.1339del p.A447Lfs*19 | Frame Shift Del (DEL) | VAF 46/120 reads (38%) | catalogued as rs879396950, COSV52972585; called by mutect2, pindel, varscan2
- ACLY | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV61250856; called by muse, mutect2, varscan2
- ACSM3 | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.378); catalogued as COSV99184022; called by muse, mutect2, varscan2
- ACTA1 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 55/210 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as COSV100796687; called by muse, mutect2, varscan2
- ACTL7A | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs755073101, COSV100452995; called by muse, mutect2, varscan2
- ACTN1 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs151249499, CM154190; called by muse, mutect2, varscan2
- ACTN4 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs372902386; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 97/114 reads (85%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM19 | c.1174C>A p.L392M | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99975837; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAM7 | c.1271G>T p.C424F | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99442805; called by muse, varscan2
- ADAMDEC1 | c.1022del p.K341Rfs*7 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs746174250; called by mutect2, varscan2
- ADAMTS2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV51123660; called by muse, mutect2, varscan2
- ADAMTS3 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776963677, COSV99709975; called by muse, mutect2, varscan2
- ADCY2 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 48/76 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100601493; called by muse, mutect2, varscan2
- ADCY8 | c.3680G>A p.R1227Q | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.885); catalogued as rs201701737, COSV53902646; called by muse, mutect2, varscan2
- ADGRA2 | c.1573del p.A525Pfs*12 | Frame Shift Del (DEL) | VAF 31/122 reads (25%) | catalogued as rs760256806, COSV59443632; called by mutect2, pindel, varscan2
- ADGRB1 | c.1318dup p.Q440Pfs*8 | Frame Shift Ins (INS) | VAF 42/145 reads (29%) | catalogued as rs772974645; called by mutect2, varscan2
- ADGRE5 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs372021393, COSV54412623; called by muse, mutect2, varscan2
- ADGRE5 | c.2161_2163del p.K721del (on ENST00000242786 / NM_078481.4; = p.K628del on NM_001784.5) | In Frame Del (DEL) | VAF 132/336 reads (39%) | catalogued as rs1381247241; called by mutect2, pindel, varscan2
- ADNP | c.3047dup p.A1017Gfs*6 | Frame Shift Ins (INS) | VAF 48/128 reads (38%) | catalogued as rs761350619; called by mutect2, varscan2
- ADNP2 | c.971dup p.A325Cfs*59 | Frame Shift Ins (INS) | VAF 54/126 reads (43%) | catalogued as rs772825390; called by mutect2, varscan2
- AFAP1 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs556804565, COSV61796412; called by muse, varscan2
- AFDN | c.2906C>T p.P969L | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs768531974, COSV100652326; called by muse, mutect2, varscan2
- AGAP4 | c.1110del p.S371Lfs*10 | Frame Shift Del (DEL) | VAF 16/118 reads (14%) | catalogued as rs782092688; called by mutect2, pindel, varscan2
- AGBL1 | c.1594T>C p.F532L | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.182); catalogued as COSV101222035; called by muse, mutect2, varscan2
- AGBL5 | c.1538A>G p.Y513C | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761872429, COSV100548792; called by muse, mutect2, varscan2
- AGRN | c.3003del p.G1002Afs*38 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | catalogued as rs763573703; called by mutect2, varscan2
- AHNAK2 | c.12254C>T p.A4085V | Missense Mutation (SNP) | VAF 182/386 reads (47%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.963); catalogued as rs372676751; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 28/59 reads (47%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKNA | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs368140660, COSV99800559; called by muse, mutect2, varscan2
- AKNA | c.1256A>G p.D419G | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99799450; called by muse, mutect2, varscan2
- AL049569.3 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100453839; called by muse, mutect2
- AL592490.1 | c.1904A>G p.N635S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1566222446, COSV101308069; called by muse, mutect2, varscan2
- ALDH1A2 | c.130_132del p.N44del | In Frame Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs759837240; called by pindel, varscan2
- ALDH9A1 | c.1493T>C p.I498T | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV61340346; called by muse, mutect2, varscan2
- ALG11 | c.52del p.Y18Ifs*35 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as COSV73000541; called by mutect2, pindel
- ALPK3 | c.2512T>C p.C838R | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV99360034; called by muse, mutect2, varscan2
- AMD1 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.967); catalogued as COSV100924443; called by muse, mutect2, varscan2
- AMER3 | c.611del p.P204Rfs*62 | Frame Shift Del (DEL) | VAF 28/94 reads (30%) | catalogued as COSV100365971, COSV58465768; called by mutect2, pindel, varscan2
- AMZ1 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs771129948, COSV100406125; called by muse, varscan2
- ANK2 | c.10931A>G p.D3644G | Missense Mutation (SNP) | VAF 65/139 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs997833950, COSV99999033; called by muse, mutect2, varscan2
- ANK3 | c.3866A>G p.H1289R (on ENST00000280772 / NM_001320874.2; = p.H423R on NM_001149.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs777500859, COSV99777810; called by muse, mutect2, varscan2
- ANKEF1 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs1217311806, COSV101000963, COSV101001076, COSV65693972; called by muse, mutect2, varscan2
- ANKRD12 | c.857G>A p.R286H | Missense Mutation (SNP) | VAF 54/97 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1356851170, COSV100040544; called by muse, mutect2, varscan2
- ANKRD12 | c.3766_3768del p.P1256del | In Frame Del (DEL) | VAF 29/89 reads (33%) | catalogued as rs757311943; called by mutect2, pindel, varscan2
- ANKRD42 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs377381576; called by muse, mutect2, varscan2
- ANKZF1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs781354105, COSV55478243; called by muse, mutect2, varscan2
- ANO2 | c.1505C>T p.A502V (on ENST00000356134 / NM_001278597.3; = p.A506V on NM_001278596.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100499481; called by muse, mutect2, varscan2
- AP4E1 | c.2776A>G p.T926A | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99956180; called by muse, mutect2, varscan2
- APLP1 | c.967C>T p.R323C | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as rs778308918, COSV55702037; called by muse, mutect2, varscan2
- APOBEC3C | c.227G>A p.C76Y | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.129); catalogued as COSV99328765; called by muse, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 18/38 reads (47%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP8 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 127/290 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.091); catalogued as rs111572783, COSV54844698; called by muse, mutect2, varscan2
- ARAP2 | c.2752+2T>C p.X918_splice | Splice Site (SNP) | VAF 17/38 reads (45%) | catalogued as COSV100393996; called by muse, mutect2
- ARHGAP22 | c.145A>C p.S49R | Missense Mutation (SNP) | VAF 99/273 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99984250; called by muse, mutect2, varscan2
- ARHGAP28 | c.1505C>T p.A502V (on ENST00000383472 / NM_001366230.1; = p.A343V on NM_001010000.3) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs774266585, COSV51632571; called by muse, mutect2, varscan2
- ARHGAP30 | c.1333C>T p.R445C | Missense Mutation (SNP) | VAF 51/128 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1489841985, COSV100920115, COSV100920193; called by muse, mutect2, varscan2
- ARHGAP36 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as COSV104370870, COSV99357116, COSV99357903; called by muse, mutect2, varscan2
- ARHGAP39 | c.2861C>T p.T954I (on ENST00000276826 / NM_001308208.2; = p.T985I on NM_025251.2) | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1421531137, COSV99430115; called by muse, mutect2, varscan2
- ARHGAP6 | c.61G>A p.A21T | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100496961; called by muse, mutect2, varscan2
- ARHGEF4 | c.107C>T p.T36I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100387434; called by muse, mutect2, varscan2
- ARID1A | c.4208A>T p.Q1403L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100250039; called by muse, mutect2, varscan2
- ASAP1 | c.1751C>T p.A584V | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100726760; called by muse, mutect2, varscan2
- ASPM | c.8154A>G p.I2718M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs150872657, COSV99659305; called by muse, mutect2, varscan2
- ASPM | c.8064G>A p.M2688I | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.176); catalogued as COSV99659307; called by muse, mutect2, varscan2
- ASPM | c.2761-2A>G p.X921_splice | Splice Site (SNP) | VAF 25/38 reads (66%) | catalogued as COSV99659312; called by muse, mutect2, varscan2
- ASTL | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs201988093; called by muse, mutect2, varscan2
- ATAD2 | c.3743T>C p.I1248T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1232231417, COSV99783919; called by muse, mutect2, varscan2
- ATAD2 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 65/215 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99783922; called by muse, varscan2
- ATF7IP2 | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV100202482, COSV61093997, COSV61095110; called by muse, mutect2, varscan2
- ATL2 | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 96/243 reads (40%) | catalogued as COSV60050674; called by muse, mutect2, varscan2
- ATP13A3 | c.3341del p.L1114Yfs*22 | Frame Shift Del (DEL) | VAF 28/59 reads (47%) | catalogued as COSV55469110; called by mutect2, pindel, varscan2
- ATP1A4 | c.69del p.I26Sfs*6 | Frame Shift Del (DEL) | VAF 41/83 reads (49%) | catalogued as rs1467294583; called by mutect2, pindel, varscan2
- ATP6V0A4 | c.1186T>C p.Y396H | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100022495; called by muse, mutect2, varscan2
- ATP8A2 | c.3359G>A p.R1120Q | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs920039996, COSV54956094; called by muse, mutect2, varscan2
- AVIL | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs192714655, COSV99142140; called by muse, mutect2, varscan2
- AVP | c.83del p.G28Afs*11 | Frame Shift Del (DEL) | VAF 54/253 reads (21%) | catalogued as COSV66672187, COSV66672270; called by mutect2, pindel, varscan2
- B4GALNT3 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 83/170 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs544500279, COSV99842289; called by muse, mutect2, varscan2
- BBS4 | c.1081T>C p.Y361H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99166372; called by muse, mutect2, varscan2
- BCAR3 | c.884G>A p.G295D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs1163643323, COSV99550078; called by muse, mutect2, varscan2
- BCAS3 | c.2435G>A p.R812Q (on ENST00000390652 / NM_001353144.2; = p.R797Q on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1396862585, COSV101174905; called by muse, mutect2, varscan2
- BCL2L11 | c.262C>A p.L88M | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100427147; called by muse, mutect2, varscan2
- BCORL1 | c.2392C>T p.Q798* | Nonsense Mutation (SNP) | VAF 48/55 reads (87%) | catalogued as COSV99498236; called by muse, mutect2, varscan2
- BDP1 | c.4817C>T p.T1606M | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1465541848, COSV100702662; called by muse, mutect2, varscan2
- BEND4 | c.1480G>A p.A494T | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101549700, COSV72469149; called by muse, mutect2, varscan2
- BEND4 | c.1066A>T p.T356S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.341); catalogued as COSV101549701; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 50/132 reads (38%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel, varscan2
- BHLHE40 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 72/149 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.042); catalogued as COSV99847887; called by muse, mutect2, varscan2
- BICD2 | c.2218G>A p.A740T | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1210812038, COSV100793955, COSV100794194; called by muse, mutect2, varscan2
- BICRA | c.2810del p.P937Hfs*10 | Frame Shift Del (DEL) | VAF 22/44 reads (50%) | catalogued as rs755506199; called by mutect2, varscan2
- BIN1 | c.1461+1G>A p.X487_splice (on ENST00000316724 / NM_001320642.1; = p.X348_splice on NM_004305.4) | Splice Site (SNP) | VAF 34/73 reads (47%) | catalogued as rs764951306, COSV52116089; called by muse, mutect2, varscan2
- BIN3 | c.338del p.K113Sfs*13 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs776003776; called by mutect2, varscan2
- BMP10 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs1420667461, COSV99770246; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 35/102 reads (34%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BPIFB6 | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 91/224 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100848467; called by muse, mutect2, varscan2
- BRD4 | c.2492C>T p.P831L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as rs1322882125, COSV99649709; called by muse, mutect2, varscan2
- BRSK1 | c.739G>A p.V247I | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.692); catalogued as COSV100473547; called by muse, mutect2, varscan2
- BTRC | c.1577G>A p.G526E (on ENST00000370187 / NM_033637.4; = p.G490E on NM_003939.5) | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100927687; called by muse, mutect2, varscan2
- BUD13 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 53/100 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778142684, COSV99496172; called by muse, mutect2, varscan2
- C14orf93 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.979); catalogued as rs779321297, COSV100136568, COSV100136855; called by muse, mutect2, varscan2
- C16orf46 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 82/172 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs372673508; called by muse, mutect2
- C1QL1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.251); catalogued as rs1287855897, COSV99492654; called by muse, mutect2, varscan2
- C1QTNF1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs1222452353, COSV100189687; called by muse, mutect2, varscan2
- C1orf141 | c.907A>C p.K303Q | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV100924260; called by muse, mutect2
- C3 | c.3998C>T p.T1333I | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV55576854; called by muse, mutect2, varscan2
- C3orf20 | c.2477C>T p.P826L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.477); catalogued as rs372038629, COSV99513267; called by muse, mutect2, varscan2
- CA10 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as rs756317806, COSV53340059; called by muse, mutect2, varscan2
- CAB39 | c.704A>G p.E235G | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99299491; called by muse, mutect2, varscan2
- CACNA1I | c.5429T>C p.I1810T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60815584; called by muse, mutect2, varscan2
- CACNA1S | c.3763A>G p.T1255A | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV100754550; called by muse, mutect2, varscan2
- CACNG2 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100268397; called by muse, mutect2, varscan2
- CACUL1 | c.165dup p.Q56Afs*30 | Frame Shift Ins (INS) | VAF 9/22 reads (41%) | catalogued as rs747095390; called by mutect2, varscan2
- CAD | c.2110T>C p.Y704H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254268; called by muse, mutect2, varscan2
- CAD | c.2341C>T p.R781C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1237542890, COSV99254270; called by muse, mutect2, varscan2
- CADM1 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59010320; called by muse, mutect2, varscan2
- CAMSAP2 | c.3789del p.K1263Nfs*19 (on ENST00000236925 / NM_001297707.2; = p.K1252Nfs*19 on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as rs770273913; called by mutect2, varscan2
- CAND2 | c.1898C>T p.A633V (on ENST00000456430 / NM_001162499.2; = p.A540V on NM_012298.3) | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as rs749368878, COSV55993503; called by muse, mutect2, varscan2
- CARD11 | c.1663dup p.R555Pfs*38 | Frame Shift Ins (INS) | VAF 35/114 reads (31%) | catalogued as rs762770988; called by mutect2, varscan2
- CARM1 | c.1211T>G p.L404R | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99449748; called by muse, mutect2, varscan2
- CASD1 | c.1802G>T p.R601M | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV99802163; called by muse, mutect2, varscan2
- CASP5 | c.727T>C p.S243P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV99507055; called by muse, mutect2, varscan2
- CAT | c.1325A>G p.Q442R | Missense Mutation (SNP) | VAF 49/90 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359875397, COSV99573061; called by muse, mutect2, varscan2
- CAVIN2 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 78/191 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as rs766125336, COSV58423489; called by muse, mutect2, varscan2
- CCDC102B | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100101773; called by muse, mutect2
- CCDC144A | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1355815929, COSV100138260; called by muse, mutect2, varscan2
- CCDC144A | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100138262; called by muse, mutect2, varscan2
- CCDC173 | c.1109dup p.N370Kfs*19 | Frame Shift Ins (INS) | VAF 8/24 reads (33%) | catalogued as rs1425656393; called by mutect2, varscan2
- CCDC174 | c.908del p.K303Rfs*2 | Frame Shift Del (DEL) | VAF 67/186 reads (36%) | catalogued as rs1229700711; called by mutect2, pindel, varscan2
- CCDC40 | c.3250G>A p.V1084M | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs546314844, COSV100162822; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC63 | c.177G>A p.Q59= | Splice Region (SNP) | VAF 30/63 reads (48%) | catalogued as COSV100370134; called by muse, mutect2, varscan2
- CCDC65 | c.268C>T p.R90* | Nonsense Mutation (SNP) | VAF 40/109 reads (37%) | catalogued as rs759201245, COSV99907820; called by muse, mutect2, varscan2
- CCDC73 | c.1341del p.E448Kfs*5 | Frame Shift Del (DEL) | VAF 18/30 reads (60%) | catalogued as rs747079826; called by mutect2, varscan2
- CCDC74A | c.776del p.P259Qfs*2 | Frame Shift Del (DEL) | VAF 92/191 reads (48%) | catalogued as rs772061983; called by mutect2, varscan2
- CCER1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs748776182, COSV62648591; called by muse, mutect2, varscan2
- CCN4 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs139058011; called by muse, mutect2, varscan2
- CD177 | c.1258del p.V420Wfs*30 | Frame Shift Del (DEL) | VAF 21/62 reads (34%) | catalogued as COSV65121341; called by mutect2, pindel, varscan2
- CD2AP | c.720del p.K240Nfs*6 | Frame Shift Del (DEL) | VAF 19/126 reads (15%) | catalogued as rs150959557; called by mutect2, pindel, varscan2
- CD5L | c.74G>A p.R25Q | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.649); catalogued as rs899486061, COSV63821614; called by muse, mutect2, varscan2
- CD93 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV55665601, COSV55667002; called by muse, mutect2, varscan2
- CDC42EP1 | c.289del p.R97Gfs*115 | Frame Shift Del (DEL) | VAF 15/76 reads (20%) | catalogued as rs762035931; called by mutect2, pindel
- CDC45 | c.1626del p.F542Lfs*5 | Frame Shift Del (DEL) | VAF 19/47 reads (40%) | catalogued as rs1224162368; called by mutect2, pindel, varscan2
- CDCA4 | c.221C>T p.T74M | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs375561549; called by muse, mutect2, varscan2
- CDH6 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); catalogued as rs762454450, COSV99417803; called by muse, mutect2, varscan2
- CDH9 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV50251365, COSV50251590; called by muse, mutect2, varscan2
- CDK11B | c.1955A>G p.K652R | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.979); catalogued as COSV100477103; called by muse, mutect2, varscan2
- CDK16 | c.1223T>C p.L408P | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1392635709, COSV99331388; called by muse, mutect2
- CDR2 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.035); catalogued as COSV99193464; called by muse, mutect2
- CEACAM5 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs376701458; called by muse, mutect2, varscan2
- CEBPE | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs371734898; called by muse, mutect2, varscan2
- CEBPG | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.432); catalogued as rs751227903, COSV99392704; called by muse, mutect2, varscan2
- CELF2 | c.1338del p.F446Lfs*17 (on ENST00000416382 / NM_001025077.3; = p.F459Lfs*17 on NM_006561.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/96 reads (33%) | catalogued as COSV59976156; called by mutect2, pindel, varscan2
- CELSR2 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 68/136 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.01); catalogued as rs534540588, COSV99602846; called by muse, mutect2, varscan2
- CELSR3 | c.5713G>A p.A1905T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.088); catalogued as COSV99372275; called by muse, mutect2, varscan2
- CENPB | c.1128G>T p.E376D | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.39); PolyPhen benign (0.093); catalogued as COSV100713225, COSV60144565; called by muse, varscan2
- CENPE | c.4654C>T p.Q1552* | Nonsense Mutation (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99476767; called by muse, mutect2, varscan2
- CEP128 | c.1016A>T p.N339I | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as COSV99382712; called by muse, mutect2, varscan2
- CEP95 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as rs782377222, COSV101616282; called by muse, mutect2, varscan2
- CFAP251 | c.2744C>T p.S915L | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.282); catalogued as rs754845886, COSV56607989; called by muse, mutect2, varscan2
- CFC1 | c.100G>A p.G34S | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs752487360, COSV99383421, COSV99383445; called by muse, mutect2, varscan2
- CFHR4 | c.1706G>A p.G569D (on ENST00000367416 / NM_001201551.2; = p.G323D on NM_006684.5) | Missense Mutation (SNP) | VAF 105/195 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1282771425, COSV99259319; called by muse, mutect2, varscan2
- CGN | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 94/160 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.183); catalogued as rs768461464, COSV99641744; called by muse, mutect2, varscan2
- CHAMP1 | c.2071G>A p.A691T | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100778704; called by muse, mutect2, varscan2
- CHD3 | c.5278T>C p.W1760R (on ENST00000330494 / NM_001005273.3; = p.W1726R on NM_005852.4) | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100177151, COSV57875866; called by muse, mutect2, varscan2
- CHD6 | c.6762G>T p.M2254I | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.027); catalogued as COSV100950481; called by muse, mutect2, varscan2
- CHD7 | c.7802A>G p.Y2601C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.88); catalogued as COSV101417949; called by muse, mutect2, varscan2
- CHRM1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs773788891, COSV61006856; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRM4 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 86/166 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769549870, COSV59182757, COSV59185444; called by muse, mutect2, varscan2
- CIITA | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as rs949731275, COSV100161253; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 15/32 reads (47%) | catalogued as rs752250702; called by mutect2, varscan2
- CKLF | c.447del p.E150Kfs*? (on ENST00000264001 / NM_016951.4; = p.E65Kfs*? on NM_016326.3) | Frame Shift Del (DEL) | VAF 27/63 reads (43%) | catalogued as rs754415052; called by mutect2, varscan2
- CLASP1 | c.3692del p.G1231Vfs*4 | Frame Shift Del (DEL) | VAF 23/74 reads (31%) | catalogued as rs749719822, COSV99752279; called by mutect2, pindel, varscan2
- CLCN1 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs145280046; called by muse, mutect2, varscan2
- CLEC14A | c.683C>T p.A228V | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100643464; called by muse, mutect2
- CLEC16A | c.1405G>A p.A469T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.993); catalogued as rs201162849, COSV68498982; called by muse, mutect2, varscan2
- CLEC9A | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 72/136 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV100872675; called by muse, mutect2, varscan2
- CLIP4 | c.1185del p.D396Ifs*19 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs1332364476; called by mutect2, pindel, varscan2
- CLUH | c.1063C>T p.R355* (on ENST00000435359; = p.R393* on NM_015229.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/34 reads (59%) | catalogued as COSV101425600; called by muse, mutect2, varscan2
- CMTM8 | c.64A>C p.N22H | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV100282309; called by muse, mutect2, varscan2
- CNNM4 | c.1952G>A p.R651H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs150945852; called by muse, mutect2, varscan2
- CNOT1 | c.1496G>A p.R499H | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs763930906, COSV57771979; called by muse, mutect2, varscan2
- CNOT3 | c.589G>A p.V197I | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as rs779539051, COSV55360346; called by muse, mutect2, varscan2
- CNTLN | c.2813A>C p.K938T | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV52093458, COSV99262418; called by muse, mutect2, varscan2
- CNTNAP1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV52853450; called by muse, mutect2, varscan2
- CNTNAP2 | c.928T>G p.L310V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.814); catalogued as COSV100661855; called by muse, mutect2, varscan2
- COG2 | c.2171A>G p.E724G | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV100794576; called by muse, mutect2, varscan2
- COL14A1 | c.2537G>A p.R846H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs901427317, COSV52849813, COSV52852703; called by muse, mutect2, varscan2
- COL17A1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139445116, CM980387, COSV100793276, COSV62226738; called by muse, mutect2, varscan2
- COL1A2 | c.2693G>A p.G898D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99798199; called by muse, mutect2, varscan2
- COL6A1 | c.2044C>T p.R682W | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as rs777378283, COSV62615628; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL7A1 | c.361G>A p.A121T | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV100094747; called by muse, mutect2
- COPZ2 | c.285del p.F95Lfs*4 | Frame Shift Del (DEL) | VAF 16/33 reads (48%) | catalogued as rs1321940394, COSV50057919; called by mutect2, pindel, varscan2
- CPT2 | c.1152del p.F384Lfs*36 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | catalogued as rs1414678698; called by pindel, varscan2
- CREM | c.772C>T p.P258S (on ENST00000429130; = p.P213S on NM_181571.3) | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as COSV100414934; called by muse, mutect2, varscan2
- CROCC | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.84); catalogued as rs1285307280, COSV100978016; called by muse, mutect2, varscan2
- CRYBG2 | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 82/271 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as rs373658132, COSV100366194; called by muse, mutect2, varscan2
- CSF3R | c.878A>C p.E293A | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.423); catalogued as COSV100117179; called by muse, mutect2, varscan2
- CSNK1A1L | c.539A>G p.H180R | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV101131055; called by muse, mutect2
- CSNK1E | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs1375092408, COSV63291923; called by muse, mutect2
- CSPP1 | c.552A>T p.E184D (on ENST00000676605; = p.E143D on NM_024790.6) | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99137944; called by muse, mutect2, varscan2
- CSRNP2 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.899); catalogued as COSV99950220; called by muse, mutect2, varscan2
- CST11 | c.114G>T p.M38I | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100776860; called by muse, mutect2
- CTCF | c.1516C>T p.Q506* | Nonsense Mutation (SNP) | VAF 17/53 reads (32%) | catalogued as COSV50531229; called by muse, mutect2, varscan2
- CTTN | c.1646G>A p.R549Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.926); catalogued as rs778284858, COSV100096971; called by muse, mutect2, varscan2
- CUBN | c.6335A>G p.Y2112C | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100911925; called by muse, mutect2, varscan2
- CUEDC1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs768323459, COSV100804632; called by muse, mutect2, varscan2
- CXXC5 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as COSV100210507; called by muse, mutect2, varscan2
- CYB5A | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs749632656, COSV100200354; called by muse, mutect2, varscan2
- CYP4B1 | c.731G>A p.R244H | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs139993247, COSV54723607; called by muse, mutect2, varscan2
- CYP4F12 | c.1304C>A p.P435Q | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.441); catalogued as COSV100215545; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | catalogued as rs751187768; called by mutect2, varscan2
- DACH2 | c.62del p.G21Afs*22 | Frame Shift Del (DEL) | VAF 11/13 reads (85%) | catalogued as COSV64172728; called by mutect2, varscan2
- DCC | c.1025C>T p.A342V | Missense Mutation (SNP) | VAF 119/276 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100497570; called by muse, varscan2
- DCST2 | c.218C>A p.S73Y | Missense Mutation (SNP) | VAF 71/126 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV55051574, COSV99791570; called by muse, mutect2, varscan2
- DCTN5 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 57/118 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.11); catalogued as rs759276671, COSV100265842; called by muse, mutect2, varscan2
- DDAH1 | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs202207743; called by muse, mutect2, varscan2
- DDX17 | c.362del p.K121Sfs*4 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs759023106; called by mutect2, varscan2
- DDX18 | c.1533T>G p.H511Q | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99604234; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 58/128 reads (45%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX60 | c.5078A>G p.N1693S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs747089851, COSV101190202; called by muse, mutect2, varscan2
- DEK | c.863G>C p.S288T | Missense Mutation (SNP) | VAF 38/43 reads (88%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV55236368; called by muse, mutect2, varscan2
- DENND1C | c.595G>A p.V199M | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV101200127; called by muse, mutect2, varscan2
- DENND6A | c.1074del p.F358Lfs*14 | Frame Shift Del (DEL) | VAF 29/88 reads (33%) | catalogued as rs34959359; called by mutect2, pindel, varscan2
- DHX29 | c.1315C>A p.L439M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99286884; called by muse, mutect2, varscan2
- DHX30 | c.3344G>A p.R1115Q (on ENST00000445061 / NM_138615.3; = p.R1076Q on NM_014966.3) | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1292255722, COSV99274534; called by muse, mutect2, varscan2
- DIP2C | c.3179C>T p.P1060L | Missense Mutation (SNP) | VAF 113/257 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759603687, COSV99789669; called by muse, mutect2, varscan2
- DIS3L2 | c.2068G>A p.A690T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs916866725, COSV99805100; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DKKL1 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.067); catalogued as rs778820244, COSV55564023; called by muse, mutect2, varscan2
- DLAT | c.478G>A p.G160R | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782189104, COSV54769419; called by muse, mutect2, varscan2
- DLC1 | c.1763G>A p.R588H (on ENST00000276297 / NM_001348081.2; = p.R151H on NM_006094.5) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs762870802, COSV52317671; called by muse, mutect2, varscan2
- DLGAP2 | c.984del p.D329Tfs*31 | Frame Shift Del (DEL) | VAF 61/293 reads (21%) | catalogued as COSV70098144; called by mutect2, pindel, varscan2
- DLGAP4 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT tolerated (0.7); PolyPhen benign (0.114); catalogued as rs758516742, COSV59423210; called by muse, mutect2, varscan2
- DMAP1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 98/229 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV60001319; called by muse, mutect2, varscan2
- DMRTA2 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 51/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1255390306, COSV101288817; called by muse, mutect2, varscan2
- DMXL1 | c.4760T>G p.L1587R | Missense Mutation (SNP) | VAF 44/102 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100223034; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAH1 | c.5097G>A p.A1699= | Splice Region (SNP) | VAF 122/259 reads (47%) | catalogued as rs974198069, COSV70226954; called by muse, mutect2, varscan2
- DNAH11 | c.10954G>A p.D3652N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.723); catalogued as rs1409530873, COSV60939970, COSV60959242; called by muse, mutect2, varscan2
- DNAH7 | c.3221del p.L1074Cfs*23 | Frame Shift Del (DEL) | VAF 18/60 reads (30%) | catalogued as rs763352877; called by mutect2, varscan2
- DNM3 | c.2084A>G p.D695G (on ENST00000355305 / NM_001350206.2; = p.D689G on NM_015569.5) | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.237); catalogued as COSV100797725; called by muse, mutect2, varscan2
- DOC2A | c.191del p.P64Lfs*27 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | catalogued as rs753153258; called by mutect2, pindel, varscan2
- DOCK1 | c.1651C>T p.L551F | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99726379; called by muse, mutect2, varscan2
- DOCK2 | c.4301A>G p.Y1434C | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99909711; called by muse, mutect2, varscan2
- DOCK5 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52402750; called by muse, mutect2
- DPP3 | c.1858C>T p.R620C | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs201663539, COSV100855387; called by muse, mutect2, varscan2
- DPP7 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.145); catalogued as COSV100857274; called by muse, mutect2, varscan2
- DRD2 | c.683G>A p.S228N | Missense Mutation (SNP) | VAF 72/202 reads (36%) | SIFT tolerated (0.88); PolyPhen benign (0.012); catalogued as COSV100669249; called by muse, mutect2, varscan2
- DSCAML1 | c.2374C>T p.P792S (on ENST00000321322; = p.P732S on NM_020693.4) | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as COSV58403760; called by muse, mutect2, varscan2
- DSP | c.2933T>C p.I978T | Missense Mutation (SNP) | VAF 71/135 reads (53%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.815); catalogued as COSV101131160; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | catalogued as rs746928635; called by mutect2, pindel, varscan2
- DUSP7 | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 20/213 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0.044); catalogued as rs763777773; called by muse, mutect2, varscan2
- DVL2 | c.1397T>C p.V466A | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99138272; called by muse, mutect2, varscan2
- DYNC1H1 | c.10730C>T p.A3577V | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64137595; called by muse, mutect2, varscan2
- DZIP1 | c.2418del p.K806Nfs*22 (on ENST00000347108; = p.K787Nfs*22 on NM_014934.5) | Frame Shift Del (DEL) | VAF 35/113 reads (31%) | catalogued as rs765594416; called by mutect2, pindel, varscan2
- DZIP1 | c.1493C>T p.S498L (on ENST00000347108; = p.S479L on NM_014934.5) | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.005); catalogued as rs755679148, COSV61264204; called by muse, mutect2, varscan2
- ECEL1 | c.1057dup p.H353Pfs*59 | Frame Shift Ins (INS) | VAF 38/118 reads (32%) | catalogued as rs762901217; called by mutect2, pindel, varscan2
- ECT2L | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 136/318 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as rs780519469, COSV62886874; called by muse, mutect2, varscan2
- EDC3 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV100165720; called by muse, mutect2, varscan2
- EFHC1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100931834; called by muse, mutect2, varscan2
- EFNB3 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 66/142 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56833244; called by muse, mutect2, varscan2
- EFTUD2 | c.1384G>A p.G462S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs372683375, COSV101274505; called by muse, mutect2, varscan2
- EGFL7 | c.56G>A p.G19D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as rs764811526, COSV100451875; called by muse, varscan2
- EGFL8 | c.417G>T p.K139N | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as COSV100246752; called by muse, mutect2, varscan2
- EGR1 | c.1000dup p.H334Pfs*13 | Frame Shift Ins (INS) | VAF 90/244 reads (37%) | catalogued as rs746692720; called by mutect2, varscan2
- EHMT2 | c.2563del p.L855Cfs*36 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs1377283633; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 40/90 reads (44%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3A | c.3713G>A p.R1238H | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.379); catalogued as COSV64961237; called by muse, mutect2, varscan2
- EIF5B | c.293del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | catalogued as rs769971529; called by mutect2, varscan2
- ELP1 | c.2958G>T p.Q986H | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV101010276; called by muse, mutect2, varscan2
- ELP3 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV56459773; called by muse, mutect2, varscan2
- ENAM | c.3020T>G p.L1007R | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV101252875; called by muse, mutect2, varscan2
- ENPP6 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.309); catalogued as COSV57070275; called by muse, mutect2, varscan2
- EP400 | c.3062T>C p.I1021T | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as rs769700878, COSV100200155; called by muse, mutect2, varscan2
- EPB41L4B | c.770A>C p.Q257P | Missense Mutation (SNP) | VAF 73/182 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101000419; called by muse, mutect2, varscan2
- ERCC6 | c.157G>A p.G53R | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.015); catalogued as rs753551732, COSV100875589; called by muse, mutect2, varscan2
- ERF | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.956); catalogued as COSV99724431; called by muse, mutect2, varscan2
- ERF | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as COSV99724434; called by muse, mutect2, varscan2
- ERMP1 | c.1951dup p.T651Nfs*25 | Frame Shift Ins (INS) | VAF 27/64 reads (42%) | catalogued as rs753821453; called by mutect2, varscan2
- ESF1 | c.1252A>G p.T418A | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs1239791102, COSV99176244; called by muse, mutect2, varscan2
- EVC | c.2770C>T p.R924C | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs772327981, COSV99380998; called by muse, mutect2, varscan2
- EXOC1 | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs546749405, COSV62121256; called by muse, varscan2
- EXOC6 | c.1708A>C p.N570H | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.688); catalogued as COSV99591287; called by muse, mutect2, varscan2
- EXPH5 | c.2006A>G p.H669R | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99760789; called by muse, mutect2
- EXPH5 | c.1774G>A p.V592I | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs111348034, COSV99760792; called by muse, mutect2, varscan2
- EYA4 | c.564C>A p.Y188* | Nonsense Mutation (SNP) | VAF 31/83 reads (37%) | catalogued as COSV100765090; called by muse, varscan2
- EYA4 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.983); catalogued as rs1199874172, COSV100765091, COSV62058181; called by muse, varscan2
- F2R | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs866890467, COSV100058261; called by muse, mutect2, varscan2
- F8 | c.3870del p.E1292Rfs*16 | Frame Shift Del (DEL) | VAF 54/85 reads (64%) | catalogued as rs1426645898, CD022147, CD0911173, COSV64270790; called by mutect2, pindel, varscan2
- FADD | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100096427, COSV100096723; called by muse, mutect2, varscan2
- FAM120C | c.1414T>G p.S472A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.075); catalogued as COSV100069489; called by muse, mutect2, varscan2
- FAM160B1 | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100985228; called by muse, mutect2, varscan2
- FAM171A1 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1306623917, COSV65316372; called by muse, mutect2, varscan2
- FAM189B | c.1531A>G p.T511A | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV100516181; called by muse, mutect2, varscan2
- FAM43B | c.250C>T p.H84Y | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as COSV100261436; called by muse, mutect2, varscan2
- FAM71C | c.311C>T p.T104I | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as rs1279340340, COSV100175624; called by muse, mutect2, varscan2
- FAM78B | c.575G>T p.R192M | Missense Mutation (SNP) | VAF 158/282 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100597297; called by muse, mutect2, varscan2
- FAM98B | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 106/211 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.309); catalogued as COSV99989031; called by muse, mutect2, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 24/54 reads (44%) | catalogued as rs746983128; called by mutect2, varscan2
- FAR1 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1405931040, COSV100701486; called by muse, mutect2, varscan2
- FASLG | c.589T>C p.F197L | Missense Mutation (SNP) | VAF 81/125 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.514); catalogued as rs776079129, COSV100390314; called by muse, mutect2, varscan2
- FAT1 | c.9683del p.P3228Lfs*42 | Frame Shift Del (DEL) | VAF 21/65 reads (32%) | catalogued as rs1010116749; called by mutect2, pindel, varscan2
- FAT4 | c.2306G>A p.G769D | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101271738; called by muse, mutect2, varscan2
- FAT4 | c.7232C>T p.T2411M | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372786128; called by muse, mutect2, varscan2
- FAXC | c.13del p.V5Lfs*13 | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | catalogued as rs773334184; called by mutect2, pindel, varscan2
- FBN1 | c.2630C>G p.S877C | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as COSV100353878; called by muse, mutect2, varscan2
- FBXO17 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.18); catalogued as COSV53069071; called by muse, mutect2
- FBXO31 | c.862C>A p.R288S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100291201, COSV61149914; called by muse, mutect2, varscan2
- FBXO41 | c.944C>T p.A315V | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1044357562, COSV54585478; called by muse, mutect2
- FBXO44 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 110/164 reads (67%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs748590247, COSV52355402; called by muse, mutect2, varscan2
- FBXO6 | c.860G>A p.R287Q | Missense Mutation (SNP) | VAF 73/99 reads (74%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs376625482; called by muse, mutect2, varscan2
- FBXO9 | c.730A>C p.S244R | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV99762189; called by muse, mutect2
- FBXW7 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.367); catalogued as COSV99898738, COSV99900887; called by muse, mutect2, varscan2
- FCGR3B | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.57); catalogued as COSV99670351; called by muse, mutect2
- FCN2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs55860122, COSV52476166; called by muse, mutect2, varscan2
- FCSK | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 63/138 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99850400; called by muse, mutect2, varscan2
- FGF13 | c.122del p.N41Tfs*3 | Frame Shift Del (DEL) | VAF 73/112 reads (65%) | catalogued as COSV59545763, COSV59549932; called by mutect2, pindel, varscan2
- FGL1 | c.371A>G p.Q124R | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101112414; called by muse, mutect2, varscan2
- FHIT | c.67T>A p.F23I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.141); catalogued as COSV100532466; called by muse, varscan2
- FKBP9 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.371); catalogued as COSV99638820; called by muse, mutect2, varscan2
- FLRT2 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV100419891; called by muse, mutect2, varscan2
- FMNL3 | c.2657G>A p.R886Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs759869506, COSV53309535; called by muse, mutect2, varscan2
- FN3KRP | c.620T>A p.L207Q | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV99484891; called by muse, mutect2, varscan2
- FNBP1L | c.219T>A p.F73L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs766939416, COSV53096948; called by muse, mutect2, varscan2
- FOXK2 | c.602C>T p.T201M | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100081716, COSV58879261; called by muse, mutect2, varscan2
- FOXL2 | c.469C>G p.P157A | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs758370933, COSV57730775; called by muse, mutect2, varscan2
- FPR2 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.344); catalogued as rs772024580, COSV100389066; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 21/108 reads (19%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FTMT | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1398561223, COSV100360425, COSV58420402; called by muse, mutect2, varscan2
- G0S2 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV65433291; called by muse, mutect2, varscan2
- G2E3 | c.1081del p.T361Lfs*16 | Frame Shift Del (DEL) | VAF 12/24 reads (50%) | catalogued as rs751355614, COSV52840527; called by mutect2, varscan2
- G3BP1 | c.8T>C p.M3T | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs769813798, COSV100663875; called by muse, mutect2, varscan2
- GABRG1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99777237; called by muse, mutect2, varscan2
- GABRG2 | c.1072C>A p.L358I (on ENST00000361925 / NM_001375343.1; = p.L318I on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62722508; called by muse, mutect2, varscan2
- GAD1 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100713724, COSV100713885; called by muse, mutect2, varscan2
- GALNS | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs377591464; called by muse, mutect2, varscan2
- GALNT14 | c.877G>T p.D293Y | Missense Mutation (SNP) | VAF 55/125 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100203962, COSV61108547; called by muse, mutect2, varscan2
- GASK1B | c.755del p.G252Afs*23 | Frame Shift Del (DEL) | VAF 7/75 reads (9%) | catalogued as rs762957217; called by mutect2, pindel
- GATC | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.062); catalogued as COSV57570337; called by muse, mutect2, varscan2
- GBE1 | c.2011del p.S671Lfs*36 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as rs780374709; called by mutect2, pindel, varscan2
- GBF1 | c.1135G>A p.V379I (on ENST00000369983 / NM_001377137.1; = p.V378I on NM_004193.3) | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.606); catalogued as rs760868521, COSV100890265; called by muse, mutect2, varscan2
- GCC2 | c.698del p.N233Ifs*12 | Frame Shift Del (DEL) | VAF 65/176 reads (37%) | catalogued as rs755348339; called by mutect2, pindel, varscan2
- GCC2 | c.2135del p.L712Cfs*16 | Frame Shift Del (DEL) | VAF 114/341 reads (33%) | catalogued as rs777909420; called by mutect2, pindel, varscan2
- GCNT4 | c.880del p.H294Ifs*14 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as rs768450027; called by mutect2, pindel, varscan2
- GDAP2 | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.828); catalogued as COSV101031806; called by muse, mutect2, varscan2
- GDI2 | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100049879; called by muse, mutect2, varscan2
- GEMIN5 | c.4427G>T p.G1476V | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as COSV99593528; called by muse, mutect2, varscan2
- GFRAL | c.300del p.K100Nfs*9 | Frame Shift Del (DEL) | VAF 42/113 reads (37%) | catalogued as rs755972268; called by mutect2, pindel, varscan2
- GGA1 | c.1093+2T>G p.X365_splice | Splice Site (SNP) | VAF 22/88 reads (25%) | catalogued as COSV100289617; called by muse, varscan2
- GGPS1 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.231); catalogued as rs1034239262, COSV51397066; called by muse, mutect2, varscan2
- GHDC | c.890-1G>T p.X297_splice | Splice Site (SNP) | VAF 26/71 reads (37%) | catalogued as COSV100054449; called by muse, mutect2, varscan2
- GIPC3 | c.281del p.G94Vfs*3 | Frame Shift Del (DEL) | VAF 44/129 reads (34%) | catalogued as rs750147424; called by mutect2, pindel, varscan2
- GJA1 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.157); catalogued as COSV99246743; called by muse, varscan2
- GJA10 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101005267; called by muse, mutect2, varscan2
- GJA8 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782753875, COSV53788064, COSV99569011; called by muse, mutect2, varscan2
- GLB1L2 | c.865C>A p.P289T | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV100335057; called by muse, mutect2, varscan2
- GLYR1 | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as COSV100423975; called by muse, mutect2, varscan2
- GPALPP1 | c.969del p.K323Nfs*5 | Frame Shift Del (DEL) | VAF 57/148 reads (39%) | catalogued as rs1566086213; called by mutect2, pindel, varscan2
- GPC6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 68/158 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760150200, COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GPR139 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as rs761772877, COSV58502353; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 76/164 reads (46%) | catalogued as rs1416935976; called by mutect2, varscan2
- GPR4 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.072); catalogued as COSV100546879; called by muse, mutect2, varscan2
- GRM2 | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.871); catalogued as rs755306821, COSV56586861; called by muse, mutect2, varscan2
- GRM3 | c.1767G>A p.M589I | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747887458, COSV100862020; called by muse, mutect2, varscan2
- GSDMC | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.049); catalogued as rs910419404, COSV52692967; called by muse, mutect2, varscan2
- GTF3C3 | c.1081del p.T361Lfs*26 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs750792116; called by mutect2, varscan2
- GUCD1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.817); catalogued as rs150870261; called by muse, mutect2, varscan2
- GUCY2C | c.2270del p.N757Mfs*8 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | catalogued as COSV53791141; called by pindel, varscan2
- GUCY2D | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as rs137853897, CM119880; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GYS1 | c.1304C>T p.T435M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs772459742, COSV99620305; called by muse, mutect2, varscan2
- GZF1 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.943); catalogued as COSV57637673; called by muse, mutect2, varscan2
- H4C7 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 35/40 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs753368947, COSV55100072; called by muse, mutect2, varscan2
- HAO2 | c.527A>C p.N176T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV100377701; called by muse, mutect2, varscan2
- HAPLN3 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61368962; called by muse, mutect2
- HBM | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100720766; called by muse, mutect2, varscan2
- HCFC1R1 | c.249del p.M84* | Frame Shift Del (DEL) | VAF 47/114 reads (41%) | catalogued as rs746547303; called by mutect2, pindel, varscan2
- HCN1 | c.1534del p.M512Cfs*19 | Frame Shift Del (DEL) | VAF 53/140 reads (38%) | catalogued as rs772669067; called by mutect2, pindel, varscan2
- HCRTR2 | c.32del p.P11Lfs*11 | Frame Shift Del (DEL) | VAF 65/165 reads (39%) | catalogued as rs755844571, COSV63794110; called by mutect2, pindel, varscan2
- HDAC7 | c.1240G>A p.G414R (on ENST00000427332; = p.G453R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.727); catalogued as rs142887723; called by muse, mutect2, varscan2
- HDLBP | c.1562C>G p.T521R | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as COSV100189736; called by muse, mutect2, varscan2
- HEATR5B | c.1303G>A p.A435T | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs1348780312, COSV51848963; called by muse, mutect2, varscan2
- HECW2 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753802852, COSV99645520; called by muse, mutect2, varscan2
- HERC1 | c.9409A>G p.T3137A | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.956); catalogued as COSV101496284; called by muse, mutect2, varscan2
- HFM1 | c.4200dup p.I1401Yfs*2 | Frame Shift Ins (INS) | VAF 22/48 reads (46%) | catalogued as rs766204131; called by mutect2, varscan2
- HIF1AN | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 50/100 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV100142526; called by muse, mutect2, varscan2
- HK2 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99308421; called by muse, mutect2, varscan2
- HK2 | c.697G>T p.G233C | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308422; called by muse, mutect2, varscan2
- HMBOX1 | c.758C>T p.T253M | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99815700; called by muse, mutect2, varscan2
- HMCN1 | c.8943C>A p.F2981L | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV99622917; called by muse, mutect2, varscan2
- HMGXB4 | c.1172del p.K391Rfs*33 | Frame Shift Del (DEL) | VAF 18/45 reads (40%) | catalogued as rs769388508; called by mutect2, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | catalogued as rs761272507; called by mutect2, varscan2
- HOXA10 | c.946_948del p.K316del | In Frame Del (DEL) | VAF 13/32 reads (41%) | catalogued as rs1264111265; called by mutect2, pindel, varscan2
- HOXB2 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100344428; called by muse, mutect2, varscan2
- HOXD1 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1412453358, COSV100514063; called by muse, varscan2
- HPD | c.199-1G>A p.X67_splice | Splice Site (SNP) | VAF 30/58 reads (52%) | catalogued as COSV56642140, COSV99999975; called by muse, mutect2, varscan2
- HRAS | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.637); catalogued as COSV99529318; called by muse, mutect2, varscan2
- HSD17B3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 67/157 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.625); catalogued as COSV100931231; called by muse, mutect2, varscan2
- HSF5 | c.1577G>A p.R526H | Missense Mutation (SNP) | VAF 79/240 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1225872264, COSV100089723, COSV60418930; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 22/60 reads (37%) | catalogued as rs773017653; called by mutect2, varscan2
- HTR3B | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491677; called by muse, mutect2, varscan2
- ICAM3 | c.953T>G p.I318S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.065); catalogued as COSV99348822; called by muse, mutect2, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | catalogued as rs759151580; called by mutect2, pindel, varscan2
- IDNK | c.332A>G p.E111G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV99461652; called by muse, mutect2, varscan2
- IDO1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs767234834, COSV53712895, COSV99503100; called by muse, mutect2, varscan2
- IFI44L | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV60728834; called by muse, mutect2, varscan2
- IFT140 | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.554); catalogued as rs536061072, COSV99559626; called by muse, mutect2, varscan2
- IFT74 | c.588-1G>C p.X196_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101195761; called by muse, mutect2, varscan2
- IFT81 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99655637; called by muse, mutect2
- IGF2R | c.4502C>A p.P1501H | Missense Mutation (SNP) | VAF 61/134 reads (46%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.69); catalogued as COSV100806723, COSV63628064; called by muse, mutect2, varscan2
- IGF2R | c.5053G>A p.D1685N | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs747421150, COSV63628763; called by muse, mutect2, varscan2
- IGHD4-17 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs377213941; called by muse, mutect2, varscan2
- IGHV1-45 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.312); catalogued as rs1314866126; called by muse, mutect2, varscan2
- IGHV3-38 | c.142G>A p.V48I | Missense Mutation (SNP) | VAF 96/199 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs369602723; called by muse, mutect2, varscan2
- IGLV1-40 | c.247T>A p.F83I | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.433); catalogued as rs764814197; called by muse, mutect2, varscan2
- IKZF1 | c.1004del p.P335Rfs*80 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as COSV58787357; called by mutect2, varscan2
- IL17RC | c.619C>T p.R207C (on ENST00000295981 / NM_153461.4; = p.R136C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs747284516, COSV99924619; called by muse, mutect2, varscan2
- IL20RB | c.279A>C p.E93D | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.096); catalogued as COSV100290902; called by muse, mutect2, varscan2
- INMT | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 155/368 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs200570990, COSV99184955; called by muse, mutect2, varscan2
- INO80E | c.42del p.K14Nfs*5 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs762875806; called by mutect2, varscan2
- INPP4B | c.2654G>A p.R885H | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs568595082, COSV53715220; called by muse, mutect2, varscan2
- INSIG2 | c.152T>A p.I51N | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99830377; called by muse, mutect2, varscan2
- INSM2 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs755781823, COSV99352863; called by muse, mutect2, varscan2
- INTS11 | c.1157A>G p.Y386C | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV100027892; called by muse, mutect2, varscan2
- INTS3 | c.1354G>A p.V452M | Missense Mutation (SNP) | VAF 125/210 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV100015543; called by muse, mutect2, varscan2
- INVS | c.2284C>T p.R762W | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs763460118, COSV99316920; called by muse, mutect2, varscan2
- IQCE | c.1616dup p.A540Gfs*5 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | catalogued as rs759821884; called by mutect2, varscan2
- IQGAP3 | c.3057-1G>A p.X1019_splice | Splice Site (SNP) | VAF 28/35 reads (80%) | catalogued as COSV63253986; called by muse, mutect2, varscan2
- ITGA2B | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | catalogued as COSV99288463; called by muse, mutect2, varscan2
- ITGA8 | c.1135G>T p.G379C | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100958681; called by muse, mutect2
- ITGB1 | c.1132C>A p.L378I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56478983; called by muse, mutect2, varscan2
- ITPR1 | c.2585A>C p.K862T (on ENST00000354582; = p.K847T on NM_002222.7) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100229107, COSV100233023; called by muse, mutect2, varscan2
- ITPR3 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 247/275 reads (90%) | SIFT tolerated (0.32); PolyPhen benign (0.424); catalogued as rs149697160; called by muse, mutect2, varscan2
- ITPRID2 | c.2888T>C p.V963A | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.266); catalogued as COSV57473384; called by muse, mutect2, varscan2
- JAG2 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 108/231 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754097964, COSV59314273; called by muse, mutect2, varscan2
- JAGN1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.038); catalogued as COSV100314680; called by muse, mutect2, varscan2
- KALRN | c.7951A>G p.S2651G (on ENST00000360013 / NM_001024660.4; = p.S954G on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.986); catalogued as COSV99360821; called by muse, mutect2, varscan2
- KAT14 | c.11G>A p.S4N | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100890017; called by muse, mutect2, varscan2
- KAT5 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100383786; called by muse, mutect2, varscan2
- KAT6A | c.1156C>T p.R386W | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs1382204077, COSV99704240; called by muse, mutect2, varscan2
- KAT6B | c.2062G>A p.V688I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs550985531, COSV99767169; called by muse, mutect2, varscan2
- KBTBD2 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.825); catalogued as rs760260609, COSV58364080; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 58/200 reads (29%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNC2 | c.982T>G p.L328V | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV100128080, COSV54363660; called by muse, mutect2, varscan2
- KCNH1 | c.2696G>A p.S899N (on ENST00000271751 / NM_172362.3; = p.S872N on NM_002238.4) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV99656566, COSV99656870; called by muse, mutect2, varscan2
- KCNH8 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs554521309, COSV60479011; called by muse, mutect2, varscan2
- KCNIP4 | c.194C>T p.T65I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as COSV100748944; called by muse, mutect2
- KCNJ14 | c.374C>T p.A125V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as COSV100655697; called by muse, mutect2, varscan2
- KCNJ4 | c.160C>T p.R54C | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100340956; called by muse, mutect2, varscan2
- KCNN3 | c.1504C>A p.Q502K (on ENST00000618040 / NM_001204087.1; = p.Q487K on NM_002249.6) | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0.053); catalogued as rs1557947697, COSV99677139; called by muse, mutect2, varscan2
- KCNT2 | c.1016A>G p.E339G | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99650956; called by muse, mutect2, varscan2
- KDF1 | c.464T>C p.M155T | Missense Mutation (SNP) | VAF 61/99 reads (62%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs565350870, COSV100264336; called by muse, varscan2
- KDF1 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs1156351594, COSV57671146; called by muse, mutect2, varscan2
- KIF13A | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 127/327 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs368453026; called by muse, mutect2, varscan2
- KIF13B | c.4072C>T p.R1358C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760240202, COSV72954257; called by muse, mutect2, varscan2
- KIF17 | c.3047A>C p.K1016T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV99928354; called by muse, mutect2
- KIF18B | c.20C>T p.T7M | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs757611142, COSV100191674; called by muse, mutect2, varscan2
- KIF1B | c.4849C>T p.R1617W (on ENST00000377086 / NM_001365952.1; = p.R1571W on NM_015074.3) | Missense Mutation (SNP) | VAF 70/113 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as rs765259892, COSV55811207; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KIF1C | c.701C>T p.T234M | Missense Mutation (SNP) | VAF 58/123 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs201655443; called by muse, mutect2, varscan2
- KIF4A | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as rs1396879790, COSV65542265; called by muse, mutect2, varscan2
- KIF4A | c.3293G>T p.G1098V | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.947); catalogued as COSV100979307; called by muse, mutect2, varscan2
- KLF7 | c.735T>C p.G245= | Splice Region (SNP) | VAF 28/59 reads (47%) | catalogued as COSV100518900; called by muse, mutect2, varscan2
- KLHL12 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 58/87 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.488); catalogued as COSV66127840; called by muse, mutect2, varscan2
- KLHL17 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 99/162 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58532095; called by muse, mutect2, varscan2
- KLHL42 | c.1194del p.C399Vfs*44 | Frame Shift Del (DEL) | VAF 98/226 reads (43%) | catalogued as rs749194179; called by mutect2, pindel, varscan2
- KMT2B | c.692G>A p.C231Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV99385825; called by muse, mutect2, varscan2
- KMT2B | c.2543C>T p.S848L | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs377636814; called by muse, mutect2, varscan2
- KMT2B | c.5157C>A p.F1719L | Missense Mutation (SNP) | VAF 220/494 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99718644; called by muse, mutect2, varscan2
- KMT2D | c.12097G>A p.V4033I | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as rs778746265, COSV99976770; called by muse, mutect2, varscan2
- KMT2D | c.6406T>C p.S2136P | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.035); catalogued as COSV99976773; called by muse, mutect2, varscan2
- KMT5C | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs772861119, COSV99726022; called by muse, mutect2
- KRI1 | c.666G>A p.T222= | Splice Region (SNP) | VAF 13/64 reads (20%) | catalogued as rs776247947, COSV100469631; called by muse, mutect2, varscan2
- KRTAP10-1 | c.282del p.C95Afs*233 | Frame Shift Del (DEL) | VAF 57/199 reads (29%) | catalogued as COSV59961454; called by mutect2, pindel, varscan2
- KSR2 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.06); catalogued as rs764042295, COSV100346525; called by muse, mutect2, varscan2
- KYNU | c.447del p.F149Lfs*12 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1422327794; called by mutect2, pindel, varscan2
- LAMB4 | c.2860A>G p.T954A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV99222352; called by muse, mutect2, varscan2
- LAMC1 | c.1400A>G p.D467G | Missense Mutation (SNP) | VAF 90/143 reads (63%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.493); catalogued as COSV99278743; called by muse, varscan2
- LARGE1 | c.1760A>G p.N587S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100504357; called by muse, mutect2, varscan2
- LARGE2 | c.1489C>G p.P497A | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV99138013; called by muse, mutect2, varscan2
- LARP4B | c.487del p.T163Hfs*47 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | catalogued as COSV60222740; called by mutect2, pindel, varscan2
- LARS2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 47/80 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs150836537; called by muse, mutect2, varscan2
- LDLRAD2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1207586255, COSV100760663; called by muse, mutect2, varscan2
- LEMD2 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 57/58 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs758833799, COSV99540375; called by muse, mutect2, varscan2
- LEMD2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146180267; called by muse, mutect2, varscan2
- LEP | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100451327; called by muse, mutect2, varscan2
- LILRA5 | c.578G>T p.G193V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV100006677; called by muse, mutect2, varscan2
- LILRB1 | c.919G>A p.A307T (on ENST00000427581; = p.A271T on NM_006669.6) | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.166); catalogued as rs201049465; called by muse, mutect2, varscan2
- LILRB4 | c.985T>C p.F329L | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99553426, COSV99553554; called by muse, mutect2, varscan2
- LINGO2 | c.1519C>T p.R507C | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.513); catalogued as rs780715183, COSV58058037, COSV58061817; called by muse, mutect2, varscan2
- LMTK3 | c.4131del p.E1378Rfs*106 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs758225154; called by mutect2, varscan2
- LNPEP | c.2885C>T p.T962I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as COSV99183461; called by muse, mutect2, varscan2
- LRBA | c.1193T>C p.L398P | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100840818; called by muse, mutect2, varscan2
- LRFN2 | c.1176del p.K393Sfs*39 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | catalogued as COSV100599362; called by mutect2, pindel, varscan2
- LRP1B | c.7174T>A p.Y2392N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101250663; called by muse, mutect2, varscan2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC4 | c.775C>T p.R259W | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1563094501, COSV99974694; called by muse, mutect2, varscan2
- LRRC49 | c.920C>T p.T307M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs753124747, COSV99536806; called by muse, mutect2, varscan2
- LRRK2 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs1555172855, COSV100108810; called by muse, mutect2, varscan2
- LRRN3 | c.1763A>G p.E588G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100066403; called by muse, mutect2, varscan2
- LRRTM3 | c.496T>C p.S166P | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100791422; called by muse, mutect2
- LRRTM3 | c.1528G>A p.E510K | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100791423; called by muse, mutect2, varscan2
- LTBP3 | c.1965del p.R656Afs*6 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as COSV57240720; called by mutect2, pindel, varscan2
- LTN1 | c.1100T>C p.I367T | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100797848; called by muse, mutect2, varscan2
- LY75 | c.3490G>A p.G1164R | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375167764; called by muse, mutect2, varscan2
- LZTS1 | c.1456C>T p.R486C | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs772213928, COSV99742562; called by muse, mutect2, varscan2
- MACF1 | c.14686del p.T4896Lfs*29 (on ENST00000372915; = p.T2829Lfs*29 on NM_012090.5) | Frame Shift Del (DEL) | VAF 48/137 reads (35%) | catalogued as rs775539898; called by mutect2, pindel, varscan2
- MACF1 | c.21100C>T p.R7034C (on ENST00000372915; = p.R5079C on NM_012090.5) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | catalogued as rs747182535, COSV57108915; called by muse, mutect2, varscan2
- MAN2A1 | c.994dup p.W332Lfs*24 | Frame Shift Ins (INS) | VAF 24/165 reads (15%) | catalogued as rs1418538270; called by mutect2, varscan2
- MAN2A1 | c.1583C>T p.A528V | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99810293; called by muse, mutect2, varscan2
- MAN2B2 | c.2143G>A p.A715T | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as COSV99576873; called by muse, mutect2, varscan2
- MAP1A | c.5110C>T p.R1704W | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1294845793, COSV55809465; called by muse, mutect2, varscan2
- MAP3K11 | c.1585C>T p.R529W | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58421087; called by muse, mutect2, varscan2
- MAP3K12 | c.741C>G p.D247E | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.154); catalogued as COSV57233563, COSV99912833; called by muse, mutect2, varscan2
- MAP3K13 | c.2502-2A>G p.X834_splice | Splice Site (SNP) | VAF 76/181 reads (42%) | catalogued as COSV99406244; called by muse, mutect2, varscan2
- MAP3K5 | c.950T>C p.L317P | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100752351; called by muse, mutect2, varscan2
- MAPK7 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs758067983, COSV100218747; called by muse, mutect2, varscan2
- MAPK8IP2 | c.2407G>A p.A803T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374276644, COSV50513272; called by muse, mutect2, varscan2
- MAPRE2 | c.847G>A p.G283R | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.691); catalogued as COSV100290124, COSV55822014; called by muse, mutect2, varscan2
- MBD6 | c.2080del p.Q694Sfs*5 | Frame Shift Del (DEL) | VAF 6/13 reads (46%) | catalogued as rs762648935; called by mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 46/94 reads (49%) | catalogued as rs746267361; called by mutect2, varscan2
- MBLAC2 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 35/74 reads (47%) | catalogued as rs142941881; called by muse, mutect2, varscan2
- MCHR1 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as rs753942647, COSV99967712; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 36/59 reads (61%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCM2 | c.1723G>A p.A575T | Missense Mutation (SNP) | VAF 10/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs949270932, COSV54031790; called by muse, mutect2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 11/27 reads (41%) | catalogued as COSV99487865; called by mutect2, pindel, varscan2
- MEX3D | c.695A>G p.D232G | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101183451; called by muse, mutect2, varscan2
- MFAP1 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 100/251 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs762059478, COSV99979554; called by muse, mutect2, varscan2
- MFF | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373848527; called by muse, mutect2, varscan2
- MFHAS1 | c.959G>A p.R320Q | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1272170911, COSV99359068; called by muse, mutect2, varscan2
- MIA2 | c.129_130del p.R43Sfs*8 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | catalogued as rs1384523915; called by pindel, varscan2
- MIEF2 | c.349C>A p.L117I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV100493409; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 63/164 reads (38%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MISP | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as rs372409482; called by muse, mutect2, varscan2
- MKX | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs879081052, COSV101008483; called by muse, mutect2, varscan2
- MLC1 | c.680A>G p.H227R | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.99); catalogued as COSV100286175; called by muse, mutect2
- MMP16 | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 70/126 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs749473846, COSV54156260, COSV99685589; called by muse, mutect2, varscan2
- MMP3 | c.190del p.I64Sfs*12 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs782038929; called by mutect2, pindel, varscan2
- MOB3C | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs771683063, COSV54718887; called by muse, mutect2, varscan2
- MON2 | c.3145T>C p.F1049L | Missense Mutation (SNP) | VAF 86/176 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.23); catalogued as COSV99741371; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs757379917; called by mutect2, varscan2
- MORN3 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 30/64 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.035); catalogued as COSV100804410; called by muse, mutect2, varscan2
- MOSPD3 | c.614G>A p.S205N | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.149); catalogued as COSV56159032; called by muse, mutect2, varscan2
- MPDZ | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs757001915, COSV59939333, COSV59939582; called by muse, mutect2, varscan2
- MPO | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138620426, COSV56564024; called by muse, mutect2, varscan2
- MPPED1 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as rs1324464781, COSV61987572; called by muse, mutect2, varscan2
- MRPL45 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as rs775042643; called by muse, mutect2, varscan2
- MS4A14 | c.1181C>A p.A394D | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100279930; called by muse, mutect2, varscan2
- MSANTD2 | c.1036C>T p.R346W (on ENST00000374979 / NM_001308027.2; = p.R294W on NM_024631.4) | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs780001210, COSV53448273; called by muse, mutect2, varscan2
- MST1R | c.931dup p.A311Gfs*26 | Frame Shift Ins (INS) | VAF 113/270 reads (42%) | catalogued as rs760002850; called by mutect2, pindel, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 26/52 reads (50%) | catalogued as rs759847587; called by mutect2, varscan2
- MTHFD2L | c.725T>C p.V242A (on ENST00000395759 / NM_001144978.2; = p.V184A on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.679); catalogued as COSV100305760; called by muse, mutect2, varscan2
- MTMR2 | c.484C>T p.R162* | Nonsense Mutation (SNP) | VAF 34/91 reads (37%) | catalogued as COSV60578484, COSV60581426; called by muse, mutect2, varscan2
- MTSS2 | c.1724G>A p.R575H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753261314, COSV99851682; called by muse, mutect2, varscan2
- MTX1 | c.133G>T p.E45* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV100366697; called by muse, mutect2, varscan2
- MTX3 | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs542176673, COSV101560464; called by muse, mutect2, varscan2
- MUC16 | c.1270A>G p.T424A | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as COSV101197492; called by muse, mutect2, varscan2
- MUC4 | c.2654C>T p.P885L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs752700892, COSV100638805; called by muse, mutect2
- MUC5B | c.15664G>A p.G5222S | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs563622514, COSV101499968; called by muse, mutect2, varscan2
- MVP | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs754161146, COSV100651455; called by muse, mutect2, varscan2
- MYBPC1 | c.431T>C p.V144A (on ENST00000550270 / NM_206820.2; = p.V169A on NM_002465.4) | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100637683; called by muse, mutect2, varscan2
- MYCBP2 | c.10813G>A p.G3605R (on ENST00000357337; = p.G3643R on NM_015057.5) | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62029413; called by muse, mutect2, varscan2
- MYH8 | c.4702T>G p.L1568V | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as rs780656237, COSV101238081; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 64/132 reads (48%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- MYO16 | c.2525del p.F842Sfs*17 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | catalogued as rs761471964; called by mutect2, varscan2
- MYO3A | c.190G>A p.A64T | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV99777815; called by muse, mutect2, varscan2
- MYO5B | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761492029, COSV53213429; called by muse, mutect2, varscan2
- MYO6 | c.3167+1G>A p.X1056_splice (on ENST00000369981; = p.X1046_splice on NM_004999.4) | Splice Site (SNP) | VAF 11/29 reads (38%) | catalogued as rs200713129; called by muse, mutect2, varscan2
- MYOM2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as rs762755462, COSV100036441; called by muse, mutect2, varscan2
- MYOM2 | c.818A>T p.Y273F | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100036442; called by muse, mutect2, varscan2
- MYOM2 | c.2944G>A p.V982M | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs143709896, COSV100036444; called by muse, mutect2, varscan2
- MYT1L | c.1521del p.C509Vfs*7 | Frame Shift Del (DEL) | VAF 71/201 reads (35%) | catalogued as COSV101220771, COSV101221394; called by mutect2, pindel, varscan2
- MZF1 | c.1258G>T p.G420C | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV99284984; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 14/43 reads (33%) | catalogued as rs770577267; called by mutect2, varscan2
- NAA40 | c.6+2T>C p.X2_splice | Splice Site (SNP) | VAF 12/58 reads (21%) | catalogued as COSV100624096; called by muse, mutect2, varscan2
- NAGA | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs564028305, COSV67169917; called by muse, mutect2, varscan2
- NALCN | c.2266G>A p.V756M | Missense Mutation (SNP) | VAF 98/218 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.633); catalogued as rs149203278, COSV51927610; called by muse, varscan2
- NALCN | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763901866, COSV51916971; called by muse, mutect2, varscan2
- NANS | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 48/95 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as rs766491062, COSV99271039; called by muse, mutect2, varscan2
- NAP1L2 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 64/77 reads (83%) | SIFT tolerated (0.58); PolyPhen benign (0.04); catalogued as COSV100999174; called by muse, mutect2, varscan2
- NAV2 | c.5947G>T p.G1983C (on ENST00000396087 / NM_001244963.2; = p.G1924C on NM_145117.5) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100215908; called by muse, mutect2
- NCAPH | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99545400; called by muse, mutect2, varscan2
- NCOA1 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.251); catalogued as rs754730103, COSV99944992; called by muse, mutect2, varscan2
- NCOA1 | c.3335G>A p.R1112H | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1316231036, COSV56045664; called by muse, mutect2, varscan2
- NCOA7 | c.2576G>C p.G859A | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99996402; called by muse, mutect2, varscan2
- NEFL | c.760C>T p.L254F | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99647792, COSV99648176; called by muse, mutect2, varscan2
- NEK7 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100954661; called by muse, mutect2, varscan2
- NEUROD4 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 250/548 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.715); catalogued as rs992833846, COSV99669665; called by muse, mutect2, varscan2
- NF1 | c.3146T>C p.V1049A | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.519); catalogued as COSV100645847; called by muse, mutect2, varscan2
- NF1 | c.4048A>G p.I1350V | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs1567858357, COSV62210635; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NF1 | c.5026G>A p.A1676T (on ENST00000358273 / NM_001042492.3; = p.A1655T on NM_000267.3) | Missense Mutation (SNP) | VAF 61/118 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.078); catalogued as rs756450772, COSV99907383, COSV99907401; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NFATC1 | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753575733, COSV99500287; called by muse, mutect2, varscan2
- NFKBIE | c.1220C>T p.A407V (on ENST00000275015; = p.A268V on NM_004556.3) | Missense Mutation (SNP) | VAF 65/74 reads (88%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as rs145497659; called by muse, mutect2, varscan2
- NFYC | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.327); catalogued as COSV100438162; called by muse, mutect2, varscan2
- NGEF | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs141871026; called by muse, mutect2, varscan2
- NINL | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs767236224, COSV54010040; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 64/150 reads (43%) | catalogued as rs145147241; called by mutect2, varscan2
- NKX2-2 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV101010464, COSV65820223; called by muse, mutect2, varscan2
- NLRC5 | c.1571T>C p.L524P | Missense Mutation (SNP) | VAF 81/178 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99346254; called by muse, mutect2, varscan2
- NLRP6 | c.1247C>T p.T416M | Missense Mutation (SNP) | VAF 99/228 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762893596, COSV56460269; called by muse, mutect2, varscan2
- NOMO1 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1228317582, COSV55061225; called by muse, mutect2, varscan2
- NOS3 | c.3545A>C p.E1182A | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV99871077; called by muse, mutect2, varscan2
- NOSIP | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.156); catalogued as COSV100182084; called by muse, mutect2, varscan2
- NOTCH2 | c.5152C>T p.R1718C | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1233590749, COSV56691983; called by muse, mutect2, varscan2
- NOTCH2 | c.598A>G p.N200D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV99862406; called by muse, mutect2, varscan2
- NPAP1 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as rs1404920860, COSV61506709, COSV61509654; called by muse, mutect2, varscan2
- NPFFR1 | c.236A>G p.N79S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99524594; called by muse, mutect2, varscan2
- NPRL3 | c.1648G>A p.V550M (on ENST00000611875 / NM_001077350.3; = p.V525M on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs188724206, COSV99549766; called by muse, varscan2
- NR2F6 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99360066; called by muse, mutect2, varscan2
- NR5A1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV101007624; called by muse, mutect2, varscan2
- NRF1 | c.1405G>T p.G469C | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56216378, COSV99781393; called by muse, mutect2, varscan2
- NRG1 | c.1459C>T p.R487W (on ENST00000405005 / NM_013964.5; = p.R492W on NM_013956.5) | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs145066694, COSV55152208; called by muse, mutect2, varscan2
- NRK | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV99686323; called by muse, mutect2, varscan2
- NTAN1 | c.831del p.K277Nfs*83 | Frame Shift Del (DEL) | VAF 35/107 reads (33%) | catalogued as COSV55073962; called by mutect2, pindel, varscan2
- NUDT1 | c.142C>T p.R48* (on ENST00000397048 / NM_198952.1; = p.R25* on NM_002452.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 18/35 reads (51%) | catalogued as rs574529054, COSV54247858; called by muse, mutect2, varscan2
- NUP133 | c.3301T>A p.F1101I | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99772462; called by muse, mutect2, varscan2
- NXN | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs757420440, COSV100402555; called by muse, mutect2, varscan2
- NXPH3 | c.272del p.P91Hfs*6 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | catalogued as rs915044706; called by mutect2, pindel, varscan2
- NYAP1 | c.1714dup p.V572Gfs*4 | Frame Shift Ins (INS) | VAF 32/86 reads (37%) | catalogued as rs778777876; called by mutect2, varscan2
- NYAP2 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs368820040, COSV56017220; called by muse, mutect2, varscan2
- OAS2 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100659996; called by muse, mutect2, varscan2
- OBSCN | c.8962G>A p.D2988N | Missense Mutation (SNP) | VAF 18/173 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.122); catalogued as rs1359578143, COSV99471201; called by muse, mutect2, varscan2
- OBSCN | c.14243G>A p.R4748H | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs377346099, COSV52773194; called by muse, mutect2, varscan2
- OBSCN | c.18113C>T p.T6038M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs531092933, COSV99471208; called by muse, varscan2
- ODF3B | c.349T>C p.Y117H | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as rs1347410406, COSV99329273; called by muse, mutect2, varscan2
- OLAH | c.419G>A p.R140H (on ENST00000378228 / NM_001039702.3; = p.R193H on NM_018324.3) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.026); catalogued as rs145059634; called by muse, mutect2, varscan2
- OLIG3 | c.287T>C p.M96T | Missense Mutation (SNP) | VAF 56/113 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100880204; called by muse, mutect2, varscan2
- ONECUT1 | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0.011); catalogued as COSV100008973; called by muse, mutect2
- OPTN | c.76dup p.H26Pfs*37 | Frame Shift Ins (INS) | VAF 48/137 reads (35%) | catalogued as rs753966040; called by mutect2, varscan2
- OR10J3 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV100171571; called by muse, mutect2, varscan2
- OR10S1 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.027); catalogued as COSV101602438, COSV73342973; called by muse, mutect2, varscan2
- OR11A1 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 119/130 reads (92%) | catalogued as COSV101010663; called by muse, mutect2, varscan2
- OR13C3 | c.80A>G p.K27R | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.06); catalogued as COSV101053228; called by muse, mutect2, varscan2
- OR2A1 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 77/81 reads (95%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs1433773236, COSV101283346; called by muse, mutect2, varscan2
- OR2T33 | c.350C>T p.A117V | Missense Mutation (SNP) | VAF 31/238 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV100531497; called by muse, mutect2, varscan2
- OR51E2 | c.467del p.F156Sfs*6 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | catalogued as rs755413956; called by mutect2, varscan2
- OR52E6 | c.295T>C p.Y99H | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100259020; called by muse, mutect2, varscan2
- OR5H1 | c.921del p.K307Nfs*? | Frame Shift Del (DEL) | VAF 19/58 reads (33%) | catalogued as rs750155763; called by mutect2, pindel, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- OTOGL | c.4847G>A p.R1616Q (on ENST00000547103; = p.R1607Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1225111265, COSV100086441; called by muse, mutect2, varscan2
- PANX2 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 58/135 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV50292058; called by muse, mutect2, varscan2
- PAQR8 | c.23G>A p.R8H | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1195271205, COSV62442341; called by muse, mutect2, varscan2
- PARP10 | c.1900C>T p.H634Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.042); catalogued as COSV100477585; called by muse, mutect2, varscan2
- PARP10 | c.1561G>A p.A521T | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.85); catalogued as rs868908655, COSV100477586; called by muse, mutect2, varscan2
- PASK | c.1538C>T p.A513V | Missense Mutation (SNP) | VAF 88/186 reads (47%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99298480; called by muse, mutect2, varscan2
- PAX1 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as rs762247909, COSV101270174; called by muse, varscan2
- PAX6 | c.1124del p.P375Hfs*7 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | catalogued as CM011452; called by mutect2, pindel, varscan2
- PBX2 | c.50del p.G17Afs*5 | Frame Shift Del (DEL) | VAF 16/26 reads (62%) | catalogued as rs773143486; called by mutect2, pindel, varscan2
- PCARE | c.3029G>T p.R1010L | Missense Mutation (SNP) | VAF 49/102 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.005); catalogued as COSV100527230; called by muse, mutect2, varscan2
- PCDH19 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 90/100 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV55268055; called by muse, mutect2, varscan2
- PCDH9 | c.2810A>G p.K937R | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100117658; called by muse, mutect2, varscan2
- PCDHA10 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 137/300 reads (46%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.022); catalogued as COSV100247148; called by muse, varscan2
- PCDHA12 | c.1583T>C p.L528P | Missense Mutation (SNP) | VAF 106/236 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs566250084, COSV56539344; called by muse, mutect2, varscan2
- PCDHA6 | c.1291G>A p.G431S | Missense Mutation (SNP) | VAF 90/246 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101129560; called by muse, mutect2, varscan2
- PCDHA8 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100969361, COSV65328168; called by muse, mutect2, varscan2
- PCDHB10 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 99/148 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.934); catalogued as rs781877019, COSV99503524; called by muse, mutect2, varscan2
- PCDHB10 | c.2125C>A p.L709M | Missense Mutation (SNP) | VAF 78/132 reads (59%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.714); catalogued as COSV99503526; called by mutect2, varscan2
- PCDHGA2 | c.2087C>T p.A696V | Missense Mutation (SNP) | VAF 102/277 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs763969101, COSV53925705; called by muse, mutect2, varscan2
- PCDHGA5 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); catalogued as rs776739278, COSV53982015; called by muse, mutect2, varscan2
- PCDHGA6 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1169979924, COSV99528851, COSV99535132; called by muse, mutect2, varscan2
- PCF11 | c.1286del p.K429Rfs*7 | Frame Shift Del (DEL) | VAF 7/26 reads (27%) | catalogued as rs747292217; called by mutect2, pindel, varscan2
- PCNX1 | c.4375A>G p.T1459A | Missense Mutation (SNP) | VAF 73/150 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV99453516; called by muse, varscan2
- PCOLCE2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749519201, COSV99930281; called by muse, mutect2, varscan2
- PDCD11 | c.3308A>T p.Y1103F | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100874216; called by muse, mutect2, varscan2
- PDE3A | c.511dup p.E171Gfs*49 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | catalogued as rs780389664; called by mutect2, varscan2
- PDE3B | c.187C>G p.P63A | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); catalogued as COSV99961851; called by muse, mutect2
- PDE3B | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as COSV99961853; called by muse, mutect2, varscan2
- PDGFB | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58648431; called by muse, mutect2, varscan2
- PDGFRB | c.3019G>A p.V1007I | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT tolerated (0.47); PolyPhen benign (0.082); catalogued as rs142762235; called by muse, mutect2, varscan2
- PGLYRP2 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs1323217929, COSV52998531, COSV99483694; called by muse, mutect2, varscan2
- PGS1 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 54/99 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs777367176, COSV99427939; called by muse, mutect2, varscan2
- PHF2 | c.1363A>G p.T455A | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100822970; called by muse, mutect2, varscan2
- PHKA2 | c.3470G>T p.S1157I | Missense Mutation (SNP) | VAF 35/43 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV101176563; called by muse, mutect2, varscan2
- PHLDA1 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV99876490; called by muse, mutect2, varscan2
- PHLPP1 | c.3736A>G p.T1246A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99407145; called by muse, mutect2, varscan2
- PHYKPL | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs770515263, COSV57424148; called by muse, mutect2, varscan2
- PIAS2 | c.1667T>C p.L556P | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100244899; called by muse, mutect2, varscan2
- PIGG | c.2237G>A p.R746Q (on ENST00000453061 / NM_001127178.3; = p.R738Q on NM_017733.4) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs962499498, COSV56318929, COSV56320311; called by muse, mutect2, varscan2
- PIGT | c.1043del p.P348Qfs*11 | Frame Shift Del (DEL) | VAF 24/58 reads (41%) | catalogued as rs749895437; called by mutect2, pindel, varscan2
- PKD1 | c.5741G>A p.G1914D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM124018, COSV99236978; called by muse, mutect2, varscan2
- PKD1 | c.2966C>T p.A989V | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs951742398; called by mutect2, varscan2
- PKNOX1 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as rs201260136, COSV99372595; called by muse, mutect2, varscan2
- PKP3 | c.1390dup p.L464Pfs*224 | Frame Shift Ins (INS) | VAF 12/24 reads (50%) | catalogued as rs757594408; called by mutect2, varscan2
- PLCB3 | c.2965A>G p.T989A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV99657051; called by muse, mutect2, varscan2
- PLCG2 | c.773G>A p.W258* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100842022, COSV100842735; called by muse, mutect2
- PLCL2 | c.1679T>A p.V560D (on ENST00000615277 / NM_001144382.2; = p.V434D on NM_015184.5) | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV101196522; called by muse, mutect2, varscan2
- PLEC | c.3938G>A p.R1313H (on ENST00000322810 / NM_201380.4; = p.R1203H on NM_000445.5) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as rs782533009, COSV100509457; called by muse, mutect2, varscan2
- PLEKHG7 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as rs1385862940, COSV100760018; called by muse, mutect2, varscan2
- PLEKHN1 | c.1043G>A p.R348H (on ENST00000379409; = p.R296H on NM_032129.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764326335, COSV100378841; called by muse, varscan2
- PLPP5 | c.389C>A p.S130Y | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV100394826; called by muse, mutect2
- PLXNA2 | c.4864G>A p.D1622N | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs780055079, COSV100884965; called by muse, mutect2, varscan2
- PLXNA4 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.36); catalogued as rs749495222, COSV100321961; called by muse, mutect2, varscan2
- PLXNB2 | c.1241G>A p.R414Q | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.067); catalogued as rs145844372, COSV100833804; called by muse, mutect2, varscan2
- PNPLA3 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1031462628, COSV99336884; called by muse, mutect2, varscan2
- POGLUT1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.533); catalogued as rs369098373; called by muse, varscan2
- POLE | c.4247C>T p.A1416V | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV100265113; called by muse, varscan2
- POLE | c.4193_4194del p.Y1398* | Frame Shift Del (DEL) | VAF 41/114 reads (36%) | catalogued as rs1323151304; ClinVar: uncertain significance; called by pindel, varscan2
- POLQ | c.517G>A p.G173S | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99951430; called by muse, mutect2, varscan2
- POLR2A | c.1693A>G p.M565V | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1402199057; called by muse, mutect2, varscan2
- POM121C | c.2981T>A p.I994N (on ENST00000607367; = p.I752N on NM_001099415.3) | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.839); catalogued as COSV99992369; called by muse, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs772047281; called by mutect2, varscan2
- POU4F1 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 12/42 reads (29%) | catalogued as COSV101020486; called by muse, mutect2, varscan2
- PPARGC1A | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV99337084; called by muse, mutect2, varscan2
- PPARGC1B | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); catalogued as COSV100494404; called by muse, mutect2, varscan2
- PPFIA1 | c.2252T>C p.L751S | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV99556667; called by muse, mutect2, varscan2
- PPFIA1 | c.2582del p.K861Sfs*27 | Frame Shift Del (DEL) | VAF 54/142 reads (38%) | catalogued as rs1565441217, COSV54138882; called by mutect2, pindel, varscan2
- PPP1R13L | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs554697880, COSV100714877, COSV62908870; called by muse, varscan2
- PPP4R3A | c.824T>C p.L275P | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100465469; called by muse, mutect2, varscan2
- PPP6R2 | c.472G>A p.G158S | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs756503205, COSV53298700, COSV99323727; called by muse, mutect2, varscan2
- PRADC1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs779009714, COSV57820732; called by muse, mutect2, varscan2
- PRCC | c.1138dup p.Q380Pfs*12 | Frame Shift Ins (INS) | VAF 84/160 reads (53%) | catalogued as rs778683789; called by mutect2, varscan2
- PRDM15 | c.2743G>A p.V915I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs774578564, COSV99519186; called by muse, mutect2, varscan2
903 further variants in this file (517 protein-altering or splice-affecting, 349 silent, 37 other) are not listed here.
